Somatic mutation profile of tumor specimen TCGA-A6-2682-01A (aliquot TCGA-A6-2682-01A-01D-1408-10) from TCGA case TCGA-A6-2682, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.3 years (25,683 days).
Specimen TCGA-A6-2682-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c96e8ea-2f24-4450-8d1a-66861785a64a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2682-10A (Blood Derived Normal), aliquot TCGA-A6-2682-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f57b0d-074b-4d79-a134-08d401e672d0

The open-access MAF lists 86 somatic variants for this specimen: 65 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 54, Silent 21, Nonsense Mutation 5, Frame Shift Ins 3, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 35/101 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SNRPD3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV53183301, COSV53184122; called by muse, mutect2, varscan2
- TP53 | c.528C>G p.C176W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519980, COSV52687391, COSV52701599, COSV52735850, COSV99377692; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: likely pathogenic / pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AP5Z1 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778239868, COSV100804170, COSV62242111; called by muse, mutect2, varscan2
- APC | c.2976dup p.K993* | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | catalogued as CI106522; called by mutect2, pindel, varscan2
- ARHGAP36 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs866578619, COSV99357958; called by muse, mutect2, varscan2
- ATP2B3 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs924902616, COSV54842708; called by muse, mutect2, varscan2
- C8orf74 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs923172574, COSV100262349, COSV100262420; called by muse, mutect2, varscan2
- CYP2F1 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs762195176, COSV58527177; called by muse, mutect2, varscan2
- DNAJB8 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs200955342, COSV59878262; called by muse, mutect2, varscan2
- EHF | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57669623; called by muse, mutect2, varscan2
- ERRFI1 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760980466; called by muse, mutect2, varscan2
- HDX | c.1954C>A p.L652M | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV99947451; called by muse, mutect2
- HEATR5B | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51853250; called by muse, mutect2, varscan2
- HSD3B2 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs139191056; called by muse, mutect2, varscan2
- HYAL2 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.447); catalogued as rs781990680; called by muse, mutect2, varscan2
- IFIT5 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs747404756; called by muse, mutect2, varscan2
- KIAA0232 | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300317; called by muse, mutect2, varscan2
- LRRC25 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs772467077; called by muse, mutect2, varscan2
- LRSAM1 | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs769238014, COSV55939727, COSV55941054; called by muse, mutect2
- LYN | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs771766572; called by muse, mutect2, varscan2
- METTL18 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1008797172, COSV53677310; called by muse, mutect2, varscan2
- NIBAN3 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as rs965230976; called by muse, mutect2, varscan2
- NPHS1 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.683); catalogued as COSV100800154; called by muse, mutect2, varscan2
- ONECUT3 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868621643; called by muse, mutect2, varscan2
- OTOF | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs777302475, COSV55521565; called by muse, mutect2, varscan2
- PLEKHA2 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs201962945; called by muse, mutect2, varscan2
- PLSCR1 | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs937759523; called by muse, mutect2
- PNO1 | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs544947906; called by muse, mutect2, varscan2
- PRDM7 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373371930; called by muse, mutect2, varscan2
- RILPL2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753404340, COSV54913611; called by muse, mutect2, varscan2
- SCN7A | c.3876G>T p.M1292I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV69269962; called by muse, mutect2, varscan2
- SEMA3D | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs763509391; called by muse, mutect2, varscan2
- SLC8A3 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV63520612; called by muse, mutect2, varscan2
- SNCB | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs772315775, COSV100031225; called by muse, mutect2, varscan2
- TCF7L2 | c.1462C>T p.R488C (on ENST00000355995 / NM_001367943.1; = p.R465C on NM_030756.5) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1264066389, COSV53335962, COSV53336193; called by muse, mutect2, varscan2
- TENM3 | c.7786G>A p.V2596M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV69311973; called by muse, mutect2
- TNRC6B | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV57291310; called by muse, mutect2
- XRRA1 | c.2249C>T p.T750I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1486921736, COSV55131108; called by muse, mutect2, varscan2
- ZNF17 | c.1117C>T p.L373F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs780250203; called by muse, mutect2, varscan2
- CAPZA3 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CCDC190 | c.455A>C p.K152T | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CD1A | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CHD2 | c.1011del p.K337Nfs*2 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by pindel, varscan2
- COL4A4 | c.1505dup p.G503Wfs*12 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- CTNNB1 | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FZD10 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2
- IQCH | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- NBEA | c.5850C>A p.N1950K | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NR2C2 | c.1405A>G p.M469V (on ENST00000393102; = p.M488V on NM_003298.5) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PCDHA6 | c.2265del p.Q756Rfs*27 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel, varscan2
- PIK3R2 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PRL | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTEN | c.1036_1045del p.Y346Kfs*3 | Frame Shift Del (DEL) | VAF 80/214 reads (37%) | called by mutect2, pindel, varscan2
- RP1 | c.5146G>A p.G1716S | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMAD4 | c.1109T>G p.V370G | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SOX9 | c.514dup p.Y172Lfs*80 | Frame Shift Ins (INS) | VAF 49/103 reads (48%) | called by mutect2, pindel, varscan2
- SPATA7 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- STAG3 | c.1769A>T p.K590M | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STX3 | c.249G>C p.E83D | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.35082G>T p.K11694N (on ENST00000591111; = p.K10767N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/176 reads (20%) | PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ZBTB43 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ABCC6 | c.1281C>T p.L427= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2
- AL049634.2 | c.474G>A p.Q158= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV67546393, COSV67546406; called by muse, mutect2, varscan2
- ANGPT4 | c.663G>A p.A221= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1477326685, COSV67922454; called by muse, mutect2, varscan2
- ARFGEF1 | c.2728C>T p.L910= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1031832389; called by muse, mutect2, varscan2
- CACNA2D3 | c.762G>A p.P254= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs757954461, COSV55511572; called by muse, mutect2, varscan2
- CLSTN3 | c.2085A>G p.T695= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- EHD3 | c.561G>C p.L187= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- HIVEP1 | c.1311G>A p.V437= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- IPO7 | c.375C>T p.R125= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- MLIP | c.645T>C p.F215= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV51427381; called by muse, mutect2, varscan2
- NLGN4Y | c.1389C>T p.Y463= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV59294754; called by muse, mutect2, varscan2
- OTOR | c.171C>T p.F57= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs867802471, COSV55722900; called by muse, mutect2, varscan2
- PCNT | c.4128C>T p.A1376= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs747661092; called by muse, mutect2, varscan2
- SLC4A10 | c.3222C>T p.H1074= (on ENST00000446997 / NM_001354461.2; = p.H1044= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs375568504; called by muse, mutect2, varscan2
- TECPR2 | c.2370C>T p.D790= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs775511129; ClinVar: likely benign; called by muse, mutect2
- TNNT3 | c.144G>A p.E48= (on ENST00000397301 / NM_001367846.1; = p.E37= on NM_006757.4) | Silent (SNP) | VAF 39/105 reads (37%) | called by muse, mutect2, varscan2
- TRIM41 | c.1683C>A p.A561= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- TXNL4A | c.228C>T p.Y76= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs201489532, COSV54099327; called by muse, mutect2, varscan2
- WNT7A | c.1008C>T p.C336= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- ZFR | c.1653T>A p.P551= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- ZNF71 | c.564C>T p.C188= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
